Gene-level copy-number profile of tumor specimen TCGA-DD-A4NE-01A from TCGA case TCGA-DD-A4NE, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 75.4 years (27,549 days).
Specimen TCGA-DD-A4NE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.91b8f43a-3bd6-40f1-9a10-e30563ada6f8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A4NE-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate.
https://portal.gdc.cancer.gov/files/513e0336-e198-42ae-824d-1046580843dc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 3; copy number 2: 7,963; copy number 4: 44,751; copy number 5: 9; copy number 6: 4,711; copy number 8: 2,349.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:102,055,252–102,657,514, 6 genes: ARL2BPP7, RNU6-329P, AL442644.2, AL442644.1, LINC00587, ZYG11AP1.
- chr18:50,795,120–53,629,990, 27 genes: MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528, LINC01917, LINC01919, RPL29P32.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
